Gene-level copy-number profile of specimen HCM-CSHL-0378-C18-85A from HCMI case HCM-CSHL-0378-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 49.6 years (18,104 days).
Specimen HCM-CSHL-0378-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8fa7b69-01de-44fc-9639-0c0a579d407d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0378-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/d3895e08-23a0-48bb-9424-6b9d9cf8b76a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 2,896; copy number 2: 55,911; copy number 3: 88; copy number 5: 9.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:93,384,487–93,385,817, 2 genes: AL137159.1, Y_RNA.
- chr7:159,231,435–159,233,377, 1 gene: PIP5K1P2.
- chr20:64,255,695–64,313,132, 4 genes: PCMTD2, AL137028.2, CICP4, LINC00266-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:77,722,492–78,066,761, 9 genes, copy number 5: NUDT7, AC092134.1, VAT1L, AC092134.2, PPIAP50, AC079414.1, CLEC3A, KRT8P22, AC079414.2.

Autosomal genes at a single copy (total copy number 1): 44. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
